Gene-level copy-number profile of tumor specimen TCGA-DK-A3IM-01A from TCGA case TCGA-DK-A3IM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.0 years (28,106 days).
Specimen TCGA-DK-A3IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.5c5e281a-87dc-48fc-9147-bf554e939e39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3ab680f-e2f2-440b-ac63-e84501eb5389

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,282; copy number 2: 28,190; copy number 3: 23,441; copy number 4: 3,604; copy number 5: 1,712; copy number 6: 42; copy number 7: 60; copy number 8: 57; copy number 9: 35; copy number 10: 96; copy number 11: 156; copy number 12: 1; copy number 13: 5; copy number 14: 54; copy number 15: 46; copy number 16: 18; copy number 25: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IM-01A-11D-A20B-01): tumor purity 0.83, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:86,594,315–86,815,171, 1 gene (within-gene range 0–2): PTPN13.
- chr5:10,664,495–11,904,446, 8 genes: AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,285 genes in 68 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,636,877–76,779,267, 4 genes, copy number 5: AC104458.1, TPI1P1, RNU6-161P, LINC02567.
- chr1:143,343,180–170,739,421, 1,034 genes, copy number 5–7 (broad region; genes not listed).
- chr1:172,138,397–172,213,499, 5 genes, copy number 8–10: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr1:188,013,642–197,146,694, 81 genes, copy number 8–16 (broad region; genes not listed).
- chr1:200,333,193–201,171,574, 18 genes, copy number 10 (within-gene range 2–10): AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9.
- chr1:204,663,872–207,738,416, 96 genes, copy number 11–14 (broad region; genes not listed).
- chr2:21,687,430–22,548,800, 8 genes, copy number 5 (within-gene range 3–5): LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884.
- chr2:59,014,354–60,100,200, 9 genes, copy number 5 (within-gene range 3–5): AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2.
- chr2:178,521,183–178,830,802, 10 genes, copy number 6 (within-gene range 2–6): TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1.
- chr3:12,257,801–13,880,071, 29 genes, copy number 7 (within-gene range 4–7): GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A.
- chr3:83,384,445–84,947,061, 8 genes, copy number 6: AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr3:115,413,476–115,486,449, 2 genes, copy number 6: AC026341.2, AC026341.3.
- chr3:166,160,021–166,181,820, 5 genes, copy number 10: MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2.
- chr3:173,396,284–174,378,005, 6 genes, copy number 5 (within-gene range 4–5): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:174,631,823–175,060,031, 2 genes, copy number 5: RN7SKP40, EEF1B2P8.
- chr4:46,918,900–47,593,486, 9 genes, copy number 6: GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2.
- chr4:113,900,284–113,979,727, 2 genes, copy number 6 (within-gene range 2–6): ARSJ, AC104779.1.
- chr5:30,733,557–31,066,132, 3 genes, copy number 5: AC026433.1, RPL19P11, AC026421.1.
- chr5:144,856,890–145,228,982, 2 genes, copy number 6 (within-gene range 3–6): AC132803.1, NAMPTP2.
- chr7:54,330,670–55,211,628, 14 genes, copy number 5: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 7: AC139365.2, AC139365.1.
- chr8:97,358,265–102,893,864, 132 genes, copy number 9–11 (broad region; genes not listed).
- chr8:126,072,587–128,564,679, 39 genes, copy number 15–25: KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:75,579,669–75,724,575, 2 genes, copy number 7: AL353780.1, OTX2P1.
- chr9:80,563,571–80,565,962, 2 genes, copy number 8: MTCO1P51, MTND2P9.
- chr9:115,252,538–116,012,965, 5 genes, copy number 5: AL355601.1, AL691420.1, U2, LINC00474, AL691426.1.
- chr9:120,244,979–123,930,152, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:132,878,027–138,203,325, 231 genes, copy number 5 (broad region; genes not listed).
- chr11:56,790,206–56,820,516, 3 genes, copy number 9: OR5G4P, OR5G5P, OR5G3.
- chr11:69,653,076–71,252,577, 34 genes, copy number 8 (within-gene range 4–8): LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3.
- chr11:79,092,848–79,989,630, 7 genes, copy number 5–8: AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr11:83,455,012–85,627,922, 7 genes, copy number 5 (within-gene range 1–9): DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1.
- chr11:87,879,473–87,917,999, 2 genes, copy number 6: AP000676.4, AP000676.1.
- chr12:126,864,465–126,874,725, 2 genes, copy number 5: AC078878.1, LINC02372.
- chr14:21,903,077–21,966,061, 7 genes, copy number 7: TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3.
- chr17:11,874,727–19,579,034, 291 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:2,688,564–4,455,307, 39 genes, copy number 10 (within-gene range 2–11): AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5.
- chr18:27,932,879–29,548,241, 10 genes, copy number 5: CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1.
- chr19:27,638,483–27,794,005, 3 genes, copy number 8 (within-gene range 3–8): ERVK-28, AC112702.1, LINC00662.
- chr20:18,507,520–18,830,153, 13 genes, copy number 5 (within-gene range 4–5): SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1.

Autosomal genes at a single copy (total copy number 1): 2,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
